Somatic mutation profile of tumor specimen TCGA-G9-6377-01A (aliquot TCGA-G9-6377-01A-11D-1961-08) from TCGA case TCGA-G9-6377, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 61.4 years (22,419 days).
Specimen TCGA-G9-6377-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38878ae0-67eb-4a51-8492-af521e03430a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6377-10A (Blood Derived Normal), aliquot TCGA-G9-6377-10A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92d1bb9f-efda-4350-9952-3be3a75f9d02

The open-access MAF lists 24 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1, 5'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF1 | c.2739A>T p.*913Cext*19 | Nonstop Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV61529605; called by muse, mutect2, varscan2
- CDH4 | c.886G>A p.V296M | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs770909673, COSV64661545; called by muse, mutect2, varscan2
- DNAJC13 | c.144+1G>T p.X48_splice | Splice Site (SNP) | VAF 19/49 reads (39%) | catalogued as COSV53457969; called by muse, mutect2, varscan2
- DST | c.10490C>T p.T3497M | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs751132203, COSV55000624; called by muse, mutect2, varscan2
- ERICH3 | c.2488G>T p.E830* | Nonsense Mutation (SNP) | VAF 13/158 reads (8%) | catalogued as COSV58603692, COSV58614001; called by muse, mutect2
- GRIK5 | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs145589136; called by muse, mutect2, varscan2
- ITGA2 | c.1974A>C p.E658D | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV56858247; called by muse, mutect2
- NOD2 | c.1736A>G p.D579G | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV56054757; called by muse, mutect2, varscan2
- OR5R1 | c.525C>G p.N175K | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV56573644; called by muse, mutect2, varscan2
- PALMD | c.1036A>T p.R346W | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs764573653, COSV54166895; called by muse, mutect2, varscan2
- PHF10 | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.469); catalogued as rs752380140, COSV59324336; called by muse, mutect2
- PRPF3 | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV61395462, COSV61396353; called by muse, mutect2
- SLCO1C1 | c.738T>A p.C246* | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | catalogued as COSV56879816; called by muse, mutect2
- SPDYE5 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 74/303 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as rs1402037278, COSV71596502; called by muse, mutect2, varscan2
- SYNPO2 | c.3323A>G p.Y1108C | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV61116853; called by muse, mutect2, varscan2
- TCERG1L | c.1266A>T p.E422D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.211); catalogued as COSV64057425; called by muse, mutect2
- TG | c.4562T>A p.L1521Q | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55093663; called by muse, mutect2
- TLL2 | c.2242G>A p.V748I | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs747500669, COSV100780564, COSV63574175; called by muse, mutect2, varscan2
- TRPM6 | c.4383T>G p.D1461E | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.028); catalogued as COSV62521954; called by muse, mutect2, varscan2
- POM121C | c.1539dup p.D514Rfs*20 (on ENST00000607367; = p.D272Rfs*20 on NM_001099415.3) | Frame Shift Ins (INS) | VAF 65/272 reads (24%) | called by mutect2, pindel, varscan2
- LRP1 | c.5298C>T p.I1766= | Silent (SNP) | VAF 28/264 reads (11%) | catalogued as COSV54525477; called by muse, mutect2, varscan2
- MYOM1 | c.2187G>T p.V729= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV55301045; called by muse, mutect2, varscan2
- ST3GAL5 | c.1005C>T p.F335= (on ENST00000377332; = p.F375= on NM_003896.4) | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as rs1168659446, COSV66150541; called by muse, mutect2, varscan2
- MARF1 | chr16:15643317 C>T | 5'Flank (SNP) | VAF 4/10 reads (40%) | catalogued as rs762137640, COSV100706202; called by muse, mutect2
